Somatic mutation profile of tumor specimen C3N-03080-02 (aliquot CPT0209240006) from CPTAC case C3N-03080, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 68.0 years (24,834 days).
Specimen C3N-03080-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e564d0f8-01e6-4e20-bffb-9d3b78854c2c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03080-31 (Blood Derived Normal), aliquot CPT0209290002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1fb1a393-2289-4993-8dcd-9888c849997d

The open-access MAF lists 166 somatic variants for this specimen: 112 protein-altering or splice-affecting, 33 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 95, Silent 33, Intron 15, Nonsense Mutation 10, 5'UTR 3, Splice Region 2, Frame Shift Del 2, 3'UTR 1, Splice Site 1, RNA 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2326_2327insTGT p.G776delinsVC | In Frame Ins (INS) | VAF 32/206 reads (16%) | catalogued as rs397516979, COSV54064203, COSV54064477, COSV54066307, COSV54066802, COSV54077015, COSV99507093; ClinVar: likely pathogenic; called by mutect2, pindel
- SHANK3 | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 16/176 reads (9%) | catalogued as rs1569097392, COSV53184238, COSV53190921; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ACTRT2 | c.461G>A p.G154D | Missense Mutation (SNP) | VAF 128/370 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs763074078; called by muse, mutect2, varscan2
- ARHGAP4 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 20/229 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs782680206, COSV100604030; called by muse, mutect2
- ATAD2 | c.3307G>A p.E1103K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.231); catalogued as COSV99784605; called by muse, mutect2, varscan2
- CAPS2 | c.1026del p.F342Lfs*30 | Frame Shift Del (DEL) | VAF 44/135 reads (33%) | catalogued as COSV60824266; called by mutect2, pindel, varscan2
- CARF | c.1577C>G p.S526* | Nonsense Mutation (SNP) | VAF 10/109 reads (9%) | catalogued as COSV57547926; called by muse, mutect2
- CCNF | c.1528C>A p.L510M | Missense Mutation (SNP) | VAF 40/347 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99564169; called by muse, mutect2, varscan2
- CFAP61 | c.3464G>A p.R1155H | Missense Mutation (SNP) | VAF 73/226 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs116375840; called by muse, mutect2, varscan2
- DMGDH | c.995-1G>A p.X332_splice | Splice Site (SNP) | VAF 125/482 reads (26%) | catalogued as COSV99668255; called by muse, mutect2, varscan2
- DMXL1 | c.9028G>T p.D3010Y | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs1281427887; called by muse, mutect2, varscan2
- DNAH6 | c.5062G>C p.D1688H | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99405860; called by muse, mutect2, varscan2
- DUS1L | c.1394C>G p.S465C | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV100152493; called by muse, mutect2, varscan2
- FAN1 | c.2514C>G p.F838L | Missense Mutation (SNP) | VAF 86/236 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as rs1379320740; called by muse, mutect2, varscan2
- FLRT2 | c.1144C>T p.Q382* | Nonsense Mutation (SNP) | VAF 8/132 reads (6%) | catalogued as COSV100420244; called by muse, mutect2
- GTF2H3 | c.716C>A p.S239Y | Missense Mutation (SNP) | VAF 32/422 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs1156614281; called by muse, mutect2
- H4C2 | c.150G>C p.L50F | Missense Mutation (SNP) | VAF 25/320 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.233); catalogued as rs369387838, COSV55138372; called by muse, mutect2
- HNRNPU | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 46/672 reads (7%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.624); catalogued as rs773969888; called by muse, mutect2
- IMPG1 | c.1545G>A p.M515I | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs376133758; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.443C>T p.S148F (on ENST00000485419 / NM_001197113.1; = p.S72F on NM_014575.3) | Missense Mutation (SNP) | VAF 34/157 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.466); catalogued as rs1294661568; called by muse, mutect2, varscan2
- JMJD1C | c.5204G>T p.R1735I | Missense Mutation (SNP) | VAF 32/452 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100550663, COSV59517914; called by muse, mutect2
- KCNJ1 | c.489G>T p.Q163H | Missense Mutation (SNP) | VAF 86/309 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756682819; called by muse, mutect2, varscan2
- KIR2DL1 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 105/425 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.96); catalogued as rs1190162220, COSV99383309; called by muse, mutect2, varscan2
- KRT26 | c.1027C>T p.Q343* | Nonsense Mutation (SNP) | VAF 22/436 reads (5%) | catalogued as rs780050927; called by muse, mutect2
- NAGLU | c.1004A>G p.Y335C | Missense Mutation (SNP) | VAF 48/539 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs768918822, CM053341; ClinVar: uncertain significance; called by muse, mutect2
- NCKAP5 | c.1232G>A p.R411Q | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.036); catalogued as rs772472479, COSV58436593, COSV58444914; called by mutect2, varscan2
- NDUFV2 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs772693645, COSV100041034; called by muse, mutect2
- NOC4L | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 48/200 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs1347030125; called by muse, mutect2, varscan2
- OR4A16 | c.202G>C p.D68H | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.834); catalogued as COSV100125101; called by muse, mutect2, varscan2
- PLEKHG5 | c.1656C>T p.I552= (on ENST00000400915 / NM_001042663.3; = p.I515= on NM_020631.6) | Splice Region (SNP) | VAF 38/413 reads (9%) | catalogued as rs762389784; called by muse, mutect2
- PPP4C | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.911); catalogued as COSV99064044; called by muse, mutect2, varscan2
- RIMBP2 | c.2652G>T p.K884N | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV55484923; called by muse, mutect2
- SERINC5 | c.84G>C p.R28S | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.012); catalogued as rs1258143784; called by muse, mutect2, varscan2
- SHC2 | c.837C>G p.I279M | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99199263; called by muse, mutect2, varscan2
- SLC27A2 | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 25/199 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1235449095, COSV51058518; called by muse, mutect2, varscan2
- SPATA18 | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 28/223 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.927); catalogued as COSV54651164; called by muse, mutect2, varscan2
- SRRM4 | c.1432C>T p.R478W | Missense Mutation (SNP) | VAF 11/204 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV57425239, COSV99938499; called by muse, mutect2
- TJP2 | c.2507C>T p.S836F | Missense Mutation (SNP) | VAF 19/202 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55269119; called by muse, mutect2
- TNN | c.2570C>T p.P857L | Missense Mutation (SNP) | VAF 160/443 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766340231; called by muse, mutect2, varscan2
- TP53 | c.813G>C p.E271D | Missense Mutation (SNP) | VAF 275/567 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV52661621, COSV52849794, COSV52892313, COSV53037823; called by muse, mutect2, varscan2
- TSPOAP1 | c.2384G>A p.R795H | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763487216; called by muse, mutect2
- TTC30B | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.021); catalogued as rs971955346; called by muse, mutect2
- USP28 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.88); catalogued as COSV50182771; called by muse, mutect2
- ZBTB7A | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1481451750; called by muse, mutect2
- ZNF208 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 60/650 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs747838999, COSV68104457; called by muse, mutect2
- ZNF264 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.056); catalogued as COSV54044081; called by muse, mutect2, varscan2
- ZNF808 | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 30/432 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as COSV100708166; called by muse, mutect2
- ALDH7A1 | c.939A>C p.L313F | Missense Mutation (SNP) | VAF 167/380 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- ATP10A | c.2695A>C p.I899L | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- AXIN2 | c.1622G>A p.C541Y | Missense Mutation (SNP) | VAF 44/392 reads (11%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- C3AR1 | c.661C>T p.H221Y | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2
- CCT5 | c.1530G>T p.L510F | Missense Mutation (SNP) | VAF 106/413 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CDK6 | c.481C>G p.L161V | Missense Mutation (SNP) | VAF 33/186 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.385); called by muse, mutect2, varscan2
- COL23A1 | c.1508T>C p.V503A | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0.127); called by muse, mutect2
- CRTC3 | c.769C>G p.Q257E | Missense Mutation (SNP) | VAF 27/261 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- CSAD | c.784G>T p.V262L (on ENST00000444623 / NM_001244705.2; = p.V289L on NM_015989.5) | Missense Mutation (SNP) | VAF 75/191 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- CYP11B1 | c.1375G>C p.E459Q | Missense Mutation (SNP) | VAF 30/448 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- DACT3 | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EFCAB5 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 29/338 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.036); called by muse, mutect2
- FAM189B | c.1406C>T p.S469F | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2
- FBXO3 | c.1264G>C p.E422Q | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.14); called by muse, mutect2
- FZD10 | c.383G>A p.W128* | Nonsense Mutation (SNP) | VAF 92/416 reads (22%) | called by muse, varscan2
- GOLGA6L2 | c.1276A>G p.M426V | Missense Mutation (SNP) | VAF 36/621 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2
- GOLGA8M | c.1751C>T p.S584F | Missense Mutation (SNP) | VAF 22/681 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- H2BC14 | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 116/350 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- HTR1E | c.232C>A p.L78M | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- KCNK1 | c.312C>A p.F104L | Missense Mutation (SNP) | VAF 9/156 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); called by muse, mutect2
- KIF21A | c.2564C>G p.S855C (on ENST00000361418 / NM_001378440.1; = p.S842C on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/450 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2
- LAMA4 | c.4460G>C p.G1487A (on ENST00000230538 / NM_001105206.3; = p.G1480A on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/353 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- LOXL2 | c.2249G>T p.G750V | Missense Mutation (SNP) | VAF 34/157 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- LRRC4 | c.1507C>T p.Q503* | Nonsense Mutation (SNP) | VAF 21/296 reads (7%) | called by muse, mutect2
- LYST | c.10805C>T p.S3602L | Missense Mutation (SNP) | VAF 9/173 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.035); called by muse, mutect2
- MPP6 | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- MSLNL | c.1609A>G p.T537A | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, varscan2
- MUC5AC | c.13712C>A p.P4571H | Missense Mutation (SNP) | VAF 74/1196 reads (6%) | SIFT deleterious (0.01); called by muse, mutect2
- NAV1 | c.1730C>T p.S577F | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NCOA3 | c.1313A>T p.N438I | Missense Mutation (SNP) | VAF 73/278 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- NEIL1 | c.547dup p.L183Pfs*10 | Frame Shift Ins (INS) | VAF 30/185 reads (16%) | called by mutect2, pindel, varscan2
- NFKBIA | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 54/780 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); called by muse, mutect2
- NIN | c.673G>C p.E225Q | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- NOD1 | c.1802A>G p.Q601R | Missense Mutation (SNP) | VAF 81/222 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NR1I3 | c.721G>C p.E241Q (on ENST00000367982 / NM_001077480.3; = p.E237Q on NM_005122.5) | Missense Mutation (SNP) | VAF 27/232 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- OR1I1 | c.206T>C p.V69A | Missense Mutation (SNP) | VAF 71/207 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OR4C4P | n.333G>C | Splice Region (SNP) | VAF 10/149 reads (7%) | called by muse, mutect2
- OR52N2 | c.887G>C p.G296A | Missense Mutation (SNP) | VAF 32/282 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- PIGT | c.827C>T p.S276L | Missense Mutation (SNP) | VAF 30/404 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.419); called by muse, mutect2
- PPM1E | c.136G>T p.E46* | Nonsense Mutation (SNP) | VAF 61/690 reads (9%) | called by muse, mutect2
- PRELID3B | c.109G>T p.D37Y | Missense Mutation (SNP) | VAF 53/199 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- RBM25 | c.1360G>C p.E454Q | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, varscan2
- REV3L | c.2027G>C p.R676T | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- RIC1 | c.2973G>C p.E991D | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RIC1 | c.3137G>C p.R1046T | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.006); called by muse, varscan2
- RIN3 | c.2366C>T p.P789L | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SEC31A | c.1654G>C p.E552Q (on ENST00000355196 / NM_001318120.1; = p.E513Q on NM_016211.4) | Missense Mutation (SNP) | VAF 9/189 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.115); called by muse, mutect2
- SETD1A | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 27/269 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SGMS2 | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC34A2 | c.951del p.S318Rfs*21 | Frame Shift Del (DEL) | VAF 64/385 reads (17%) | called by mutect2, pindel, varscan2
- SMG8 | c.2032A>T p.K678* | Nonsense Mutation (SNP) | VAF 30/314 reads (10%) | called by muse, mutect2
- SSR3 | c.74C>A p.S25* | Nonsense Mutation (SNP) | VAF 67/263 reads (25%) | called by muse, mutect2, varscan2
- TG | c.5077G>C p.E1693Q | Missense Mutation (SNP) | VAF 50/506 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.077); called by muse, mutect2
- TMEM255B | c.542T>A p.I181N | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); called by muse, mutect2
- TRIM49C | c.100T>A p.F34I | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- TRIP11 | c.2545G>C p.E849Q | Missense Mutation (SNP) | VAF 10/219 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- TSGA10 | c.1559C>G p.S520* | Nonsense Mutation (SNP) | VAF 11/188 reads (6%) | called by muse, mutect2
- UBTD2 | c.536G>C p.R179T | Missense Mutation (SNP) | VAF 47/275 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- USH1G | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VSIG10L | c.667C>G p.L223V | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- WDR72 | c.3272C>T p.S1091L | Missense Mutation (SNP) | VAF 43/550 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); called by muse, mutect2
- XAB2 | c.31G>C p.E11Q | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.237); called by muse, mutect2
- ZNF17 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 12/341 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2
- ZNF729 | c.2543G>T p.G848V | Missense Mutation (SNP) | VAF 30/615 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- ZNF781 | c.322C>G p.Q108E | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.366); called by muse, mutect2
- APCDD1L | c.147G>A p.A49= | Silent (SNP) | VAF 17/233 reads (7%) | catalogued as rs772487718; called by muse, mutect2
- ARAP3 | c.453T>G p.T151= | Silent (SNP) | VAF 105/229 reads (46%) | called by muse, mutect2, varscan2
- CCT3 | c.72T>G p.S24= | Silent (SNP) | VAF 9/151 reads (6%) | called by muse, mutect2
- CHRM2 | c.387G>A p.L129= | Silent (SNP) | VAF 33/334 reads (10%) | catalogued as rs753589267; called by muse, mutect2
- CST1 | c.252C>T p.F84= | Silent (SNP) | VAF 22/381 reads (6%) | called by muse, mutect2
- DLL3 | c.774C>T p.L258= | Silent (SNP) | VAF 39/570 reads (7%) | called by muse, mutect2
- DNAI3 | c.1497C>A p.S499= | Silent (SNP) | VAF 23/199 reads (12%) | called by muse, mutect2, varscan2
- DOCK8 | c.5727G>A p.L1909= | Silent (SNP) | VAF 105/343 reads (31%) | called by muse, mutect2, varscan2
- ELFN2 | c.252C>G p.L84= | Silent (SNP) | VAF 72/314 reads (23%) | called by muse, mutect2, varscan2
- EML4 | c.1015C>T p.L339= | Silent (SNP) | VAF 28/390 reads (7%) | catalogued as rs1188218753, COSV59297149; called by muse, mutect2
- ENKD1 | c.315G>A p.L105= | Silent (SNP) | VAF 13/110 reads (12%) | catalogued as COSV54669916; called by muse, mutect2, varscan2
- FAM71E2 | c.294C>T p.L98= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as rs943193894; called by muse, mutect2
- GFI1B | c.660C>T p.F220= | Silent (SNP) | VAF 29/263 reads (11%) | catalogued as rs374075090; called by muse, mutect2, varscan2
- GPR157 | c.327C>A p.V109= | Silent (SNP) | VAF 32/203 reads (16%) | catalogued as rs763996016; called by muse, mutect2, varscan2
- H1-8 | c.141G>A p.P47= | Silent (SNP) | VAF 11/112 reads (10%) | catalogued as rs1327803702; called by muse, varscan2
- ITGB7 | c.2244C>T p.L748= | Silent (SNP) | VAF 31/474 reads (7%) | called by muse, mutect2
- ITSN1 | c.4792T>C p.L1598= | Silent (SNP) | VAF 50/171 reads (29%) | catalogued as rs1391103034; called by muse, mutect2, varscan2
- KSR1 | c.1791C>T p.I597= (on ENST00000644974 / NM_001367810.1; = p.I482= on NM_014238.2) | Silent (SNP) | VAF 113/678 reads (17%) | catalogued as rs778099345, COSV99258184; called by muse, mutect2, varscan2
- MRPL34 | c.201C>T p.V67= | Silent (SNP) | VAF 21/211 reads (10%) | called by muse, mutect2
- MYT1 | c.3120G>A p.K1040= | Silent (SNP) | VAF 54/178 reads (30%) | called by muse, mutect2, varscan2
- NKX1-1 | c.966G>A p.S322= | Silent (SNP) | VAF 34/116 reads (29%) | catalogued as rs775502070; called by muse, mutect2, varscan2
- NXPH4 | c.858T>C p.F286= | Silent (SNP) | VAF 21/331 reads (6%) | called by muse, mutect2
- PDC | c.399C>T p.I133= | Silent (SNP) | VAF 22/219 reads (10%) | called by muse, mutect2, varscan2
- POLA1 | c.1005A>T p.A335= | Silent (SNP) | VAF 48/78 reads (62%) | called by muse, mutect2, varscan2
- SEL1L3 | c.2430C>A p.I810= | Silent (SNP) | VAF 11/83 reads (13%) | called by muse, mutect2, varscan2
- SH3GL3 | c.249C>T p.T83= | Silent (SNP) | VAF 27/227 reads (12%) | catalogued as rs146975595; called by muse, mutect2, varscan2
- SPTBN2 | c.1380C>T p.V460= | Silent (SNP) | VAF 15/126 reads (12%) | catalogued as rs529823815; called by muse, mutect2, varscan2
- STAG2 | c.2994A>C p.A998= | Silent (SNP) | VAF 18/88 reads (20%) | called by muse, mutect2, varscan2
- STOML1 | c.63G>C p.S21= | Silent (SNP) | VAF 41/238 reads (17%) | called by muse, mutect2, varscan2
- TCP1 | c.414T>A p.V138= | Silent (SNP) | VAF 17/230 reads (7%) | catalogued as COSV58459075; called by muse, mutect2
- TRIM46 | c.2193C>T p.I731= | Silent (SNP) | VAF 78/357 reads (22%) | catalogued as rs766467237, COSV58118756; called by muse, mutect2, varscan2
- ZNF691 | c.810T>C p.F270= (on ENST00000372502; = p.F239= on NM_015911.3) | Silent (SNP) | VAF 67/346 reads (19%) | catalogued as rs748968965; called by muse, mutect2, varscan2
- ZSWIM5 | c.162C>T p.L54= | Silent (SNP) | VAF 21/266 reads (8%) | catalogued as COSV62734765, COSV62736099; called by muse, mutect2
- AC069544.2 | c.-151-21C>T | Intron (SNP) | VAF 24/143 reads (17%) | called by muse, mutect2, varscan2
- AGAP1 | c.164-38267C>G | Intron (SNP) | VAF 7/144 reads (5%) | called by muse, mutect2
- AKT1 | c.633+17A>T | Intron (SNP) | VAF 8/85 reads (9%) | called by muse, mutect2
- AP2A2 | c.67+14792C>G | Intron (SNP) | VAF 24/356 reads (7%) | called by muse, mutect2
- ASH1L | c.5828+4424C>T | Intron (SNP) | VAF 320/865 reads (37%) | catalogued as rs1374851390; called by muse, mutect2, varscan2
- BAIAP2 | c.54+1630T>G | Intron (SNP) | VAF 24/396 reads (6%) | called by muse, mutect2
- BDNF | c.-5G>A | 5'UTR (SNP) | VAF 20/278 reads (7%) | catalogued as rs982182462; called by muse, mutect2
- EXOSC4 | c.172-215G>C | Intron (SNP) | VAF 11/105 reads (10%) | called by muse, mutect2, varscan2
- GTF2IRD2P1 | n.2190G>A | RNA (SNP) | VAF 56/901 reads (6%) | called by muse, mutect2
- GZMB | chr14:24634213 C>T | 5'Flank (SNP) | VAF 28/304 reads (9%) | called by muse, mutect2
- LCN12 | c.-29C>G | 5'UTR (SNP) | VAF 28/268 reads (10%) | called by muse, mutect2
- LCN12 | c.550+384C>T | Intron (SNP) | VAF 17/120 reads (14%) | called by muse, varscan2
- LIX1 | c.483+2160C>G | Intron (SNP) | VAF 10/164 reads (6%) | called by muse, mutect2
- MXD3 | c.177-26C>T | Intron (SNP) | VAF 20/313 reads (6%) | called by muse, mutect2
- NALCN | c.2118+173G>A | Intron (SNP) | VAF 4/22 reads (18%) | called by muse, varscan2
- OR5AU1 | c.-61C>A | 5'UTR (SNP) | VAF 50/196 reads (26%) | called by muse, mutect2, varscan2
- PLOD2 | c.1614+33C>G | Intron (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- RPL27A | c.143+244T>C | Intron (SNP) | VAF 23/366 reads (6%) | catalogued as rs1402405796; called by muse, mutect2
- TNRC18 | c.187+626G>T | Intron (SNP) | VAF 40/199 reads (20%) | called by muse, mutect2, varscan2
- UBE2J2 | c.131+1716C>G | Intron (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2, varscan2
- XIRP2 | c.*408A>C | 3'UTR (SNP) | VAF 7/125 reads (6%) | called by muse, mutect2
